CCDI case PBCLSC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/f408be3b-7070-449e-8bc8-640b0967a49f

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Malignant tumor, spindle cell type: ICD-O-3 morphology code: 8004/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of thorax; Age at diagnosis: 0.1 years (34 days).

Biospecimens (3 samples)
- Sample 0DV7GR: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DV7GV: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DV7GY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
